Surgical pathology report (de-identified scan), TCGA case TCGA-41-3393, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-3393-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Left posterior parietal brain tumor
- B. Left posterior parietal brain tumor
- C. Left posterior parietal brain tumor

REPORT REVISED ON [REDACTED] AT [REDACTED] BY [REDACTED]

CLINICAL NOTES

Left posterior parietal brain tumor

GROSS DESCRIPTION

A. Received in a container labeled with the patient's name,

medical record number and "left posterior parietal brain tumor." The specimen consists of multiple fragments of soft tan tissue which measure 1.2 x 0.8 x 0.5 cm. in aggregate. A portion is

submitted for tissue procurement. The remainder is submitted in block A1.

B. Container B is labeled with the patient's name, medical record number and "left posterior parietal brain tumor". The specimen consists of a single fragment of firm tan tissue measuring 0.8 x 0.5 x 0.5 cm. [REDACTED]

C. Received fresh subsequently fixed in formalin labeled "left posterior parietal brain tumor" are multiple pink-tan, friable tissue fragments which have an aggregate measurement of 1.5 x 1. x 0.5 cm. The specimen is entirely submitted in one cassette. AS-1. [REDACTED]

REPORT REVISED ON [REDACTED] AT [REDACTED] BY [REDACTED]

MICROSCOPIC DESCRIPTION

A, B, C. Sections of the left posterior parietal brain tumor submitted in specimens A, B and C demonstrate glioblastoma multiforme.

[page 2 of 2]
MICROSCOPIC DESCRIPTION

3x2

REPORT REVISED ON AT BY

DIAGNOSIS

A. Left posterior parietal brain tumor, biopsy: Glioblastoma
multiforme.

B. Left posterior parietal brain tumor, biopsy: Glioblastoma
multiforme.

C. Left posterior parietal brain tumor, biopsy: Glioblastoma
multiforme.

REPORT REVISED ON AT BY

Addition of dictation for specimen C.

--- End Of Report ---

Source: NCI Genomic Data Commons file f53e444d-4315-4fba-b938-4adbea4c8d5d (TCGA-41-3393.EF63AAC8-BF7A-420B-BD2C-75B3112B836F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).